Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A1KZ, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A1KZ-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: Gastric & Mixed Tumo
Account #: [REDACTED] Date of Procedure:
DOB: [REDACTED] Date of Receipt:
Physician: [REDACTED]
CC: [REDACTED]

....

Specimens Submitted:

- 1: SP: Retroperitoneal mass, right kidney, right adrenal
- 2: SP: Right colon and hepatic flexure
- 3: SP: Final liver margin

DIAGNOSIS:

1. RIGHT RETROPERITONEAL MASS, RIGHT KIDNEY AND ADRENAL, RADICAL RESECTION:
- HIGH GRADE DEDIFFERENTIATED LIPOSARCOMA.
- TUMOR SIZE: 30 X 25 X 6 CM (WEIGHT 1825 GRAMS).
- THE DEDIFFERENTIATED COMPONENT PREDOMINATES AND SHOWS A VARIEGATED APPEARANCE, RANGING FROM HIGH GRADE MALIGNANT FIBROUS HISTIOCYTOMA-LIKE GROWTH PATTERN TO FOCAL AREAS RESEMBLING LOW GRADE MYXOFIBROSARCOMA.
- AREAS OF WELL-DIFFERENTIATED LIPOSARCOMA, LIPOMA LIKE AND SCLEROSING SUBTYPES, ARE ALSO PRESENT.
- THE DEDIFFERENTIATED COMPONENT INVADDES KIDNEY PARENCHYMA.
- ADRENAL GLAND APPEARS TO BE FOCALLY ENCASED BY THE LOW GRADE COMPONENT.
- TUMOR IS PREDOMINATELY VIABLE
- ALTHOUGH GROSSLY THE TUMOR APPEARED TO BE SURROUNDED BY A SMOOTH LINED MEMBRANE, MICROSCOPICALLY IT EXTENDS TO INKED SURFACE.
- URETER, RENAL VEIN AND ARTERY MARGINS ARE NEGATIVE.
- KIDNEY WITH MINUTE INCIDENTAL MICROPAPILLARY ADENOMA
2. RIGHT COLON AND HEPATIC FLEXURE, EXCISION:
- COLON SEGMENT, NEGATIVE FOR TUMOR.
3. FINAL LIVER MARGIN, EXCISION:
- LIVER PARENCHYMA WITH SUBCAPSULAR HEMORRHAGE AND REACTIVE CHANGES. NO TUMOR IDENTIFIED.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

** Continued on next page **

ICD-0-3
Dedifferentiated liposarcoma 8858/3
Site. retroperitoneum C48.0

2/2/11
hw

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

MRN: [REDACTED]

Account #: [REDACTED]

Accession #: [REDACTED]

Physician: [REDACTED]

Service: General & Mixed Tumor

Page 2 of 3

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is received fresh, labeled, "retroperitoneal mass, right kidney, right adrenal", and consists of a 1825 gm, 30 x 25 x 6 cm lobulated mass covered by a smooth lining. There is a 2 x 1 x 0.5 cm adrenal gland and an adjacent kidney with uninvolved pelvis, ureter (12 cm in length x 0.4 cm in diameter), artery (0.3 cm in length x 0.3 cm diameter) and vein (3 cm in length x 0.3 cm diameter). The external surface is inked black. Cross-sections show the kidney capsule enveloped by tumor. The kidney measures 12 x 6 x 3 cm with a 1.1 cm thick cortex and a well-defined cortico-medullary junction. The tumor consists of a heterogenous lobulated mass with necrotic areas of degenerating yellow, friable tumor, hemorrhage and interspersed tan-yellow smooth nodules. Representative sections submitted.

Summary of sections:

AR - adrenal gland

UVAM - ureter, vein, artery margin

K - normal kidney

KT - tumor in relation to kidney

RT - representative sections of tumor including margin

2. The specimen is received fresh, labeled, "right colon and hepatic flexure" and consists of a 7 cm in length x 2.5 cm in diameter portion of un-oriented colon with a portion of attached mesentery (6 x 3 x 0.5 cm). No distinct masses are identified. Representatively submitted.

Summary of sections:

M - mucosal margins

R - representative sections

3. The specimen is received in formalin, labeled, "final liver margin" and consists of a friable 4 x 2 x 1 cm portion of liver with no attached masses. The specimen is inked black and entirely submitted.

Summary of sections:

U - undesignated

Summary of Sections:

Part 1: SP: Retroperitoneal mass, right kidney, right adrenal

Block	Sect. Site	PCs
-------	------------	-----

** Continued on next page **

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Patient:

MRN:

Account #:

Accession #:

Physician:

Service: Gastric & Mixed Tumo

Page 3 of 3

1	AR	1
1	K	1
4	KT	4
25	RT	25
1	UVAM	1

Part 2: SP: Right colon and hepatic flexure

Block	Sect.	Site	PCs
2		M	2
2		R	2

Part 3: SP: Final liver margin

Block	Sect.	Site	PCs
2		U	2

** End of Report **

Source: NCI Genomic Data Commons file 57c21477-9087-4fbe-a0ec-40c575fb9d41 (TCGA-DX-A1KZ.8CA84186-49D2-4762-9658-45D2C303E7EB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).